Gene-level copy-number profile of tumor specimen MP2PRT-PAVFRE-TMP1-A from MP2PRT case MP2PRT-PAVFRE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (591 days).
Specimen MP2PRT-PAVFRE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6df6813-b8a7-4502-b2dd-7df42ecc8a36.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVFRE-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/beeec8a5-7e81-4218-a625-f7392f3bcb7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 98; copy number 2: 39,194; copy number 3: 17,683; copy number 4: 1,926; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,176,328–89,192,752, 2 genes (within-gene range 0–2): IGKV2-24, IGKV3-25.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:60,914,407–60,964,196, 5 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.

Autosomal genes at a single copy (total copy number 1): 98. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
